Surgical pathology report (de-identified scan), TCGA case TCGA-EK-A2H0, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Gynecologic Oncology Group, specimen TCGA-EK-A2H0-01A (Primary Tumor).

[page 1 of 4]
PAGE:1

PATIENT:

ACCT #:

5 LOC:

U#:

AGE/SX:

/F

RM/BED:

REG:

REG DR:

STATUS:

TLOC:

DIS:

SPEC #:

Obtained:

Subm Dr:

STATUS:

Received:

CLINICAL HISTORY:

LEFT EXTERNAL ILIAC (EVALUATE FOR SUCCEED)

SPECIMEN/PROCEDURE:

1. LYMPH NODE - RIGHT OBTURATOR
2. LYMPH NODE - RIGHT EXTERNAL ILIAC
3. LYMPH NODE - RIGHT COMMON ILIAC
4. LYMPH NODE - RIGHT EXTERNAL ILIAC
5. LYMPH NODE - RIGHT OBTURATOR
6. CERVIX - BIOPSY TUMOR
7. LYMPH NODE - LEFT EXTERNAL ILIAC
8. LYMPH NODE - LEFT OBTURATOR
9. LYMPH NODE - LEFT COMMON ILIAC
10. LYMPH NODE - LEFT PARA-AORTIC
11. LYMPH NODE - LEFT EXTERNAL ILIAC

ICD-0-3

Carcinoma, squamous cell, large cell,
Keratinizing 8071/3

Site: Cervix, NOS C 53.9

fw 6/16/11

IMPRESSION:

- 1) RIGHT OBTURATOR LYMPH NODE:
. Six lymph nodes are negative for tumor (0/6).
- 2) RIGHT EXTERNAL ILIAC LYMPH NODE:
. One lymph node are negative for tumor (0/1).
- 3) RIGHT COMMON ILIAC LYMPH NODE:
. Seven lymph nodes are negative for tumor (0/7).
- 4) RIGHT EXTERNAL ILIAC LYMPH NODE:
. Three lymph nodes are negative for tumor (0/3).
- 5) RIGHT OBTURATOR ILIAC LYMPH NODE:
. Two lymph nodes are negative for tumor (0/2).
- 6) CERVICAL BIOPSY TUMOR:
. Squamous cell carcinoma, large cell keratinizing with stromal invasion.
- 7) LEFT EXTERNAL ILIAC LYMPH NODE:
. Seven lymph nodes are negative for tumor (0/7).
- 8) LEFT OBTURATOR ILIAC LYMPH NODE:

** CONTINUED ON NEXT PAGE **

[page 2 of 4]
IMPRESSION: (continued)

Two lymph nodes are negative for tumor (0/2).

9) LEFT COMMON ILIAC LYMPH NODE:

One lymph node is negative for tumor (0/1).

10) LEFT PARAAORTIC ILIAC LYMPH NODE:

Two lymph nodes are negative for tumor (0/2).

11) LEFT EXTERNAL ILIAC LYMPH NODE:

Four lymph nodes are negative for tumor (0/4).

Dictated

Entered:

COMMENT:

Thirty-five lymph nodes are negative for tumor.

Entered:

SPECIAL STAINS/PROCEDURES:

Mucicarmin stain is negative.

Dictated by:

GROSS DESCRIPTION:

- 1) Received labeled with the patient's name and "right obturator" is a 2.5 x 2.0 x 0.9 cm portion of yellow gold to pink tan fibroadipose tissue dissected for possible lymph nodes. Six possible lymph nodes identified ranging from 0.3 cm to 1.5 cm in greatest dimension and submitted as follows:

CASSETTE SUMMARY

Cassette 1A: Five possible lymph nodes.

Cassettes 1B-1C: One lymph node bisected.

- 2) Received labeled with the patient's name and "right external iliac" is a pink to pale tan apparent lymph node with a small amount of adherent yellow gold adipose tissue. The specimen is 1.0 x 1.0 x 0.9 cm. The adherent adipose tissue is dissected free. The lymph node is bisected.
- 3) Received labeled with the patient's name and "right common iliac" is a 2.2 x 2.0 x 1.0 cm aggregate of pink to pale tan to yellow gold portions of fibroadipose tissue dissected for possible lymph nodes. Received are seven pink to pale tan tissue fragments ranging from 0.6 cm to 2.0 cm in greatest dimension. These fragments are submitted as follows:

** CONTINUED ON NEXT PAGE **

[page 3 of 4]
GROSS DESCRIPTION: (continued)**CASSETTE SUMMARY**

Cassette 3A: Five possible lymph nodes.
Cassette 3B: Two possible lymph nodes.

- 4) Received labeled with the patient's name and "right external iliac" are three portions of yellow gold to pink tan fibroadipose tissue ranging from 1.0 cm to 2.2 cm in greatest dimension. The specimen is dissected for possible lymph nodes. Three possible lymph nodes identified ranging from 0.5 to 1.4 cm in greatest dimension and submitted as follows:

CASSETTE SUMMARY

Cassette 4A: Two possible lymph nodes.
Cassette 4B: One lymph node bisected.

- 5) Received labeled with the patient's name and "right obturator" is a 3.2 x 2.0 x 1.0 cm aggregate of yellow gold to pink tan fibroadipose tissue dissected for possible lymph nodes. Two possible lymph nodes identified ranging from 0.8 cm to 2.0 cm in greatest dimension and submitted as follows:

CASSETTE SUMMARY

Cassette 5A: One lymph node entirely submitted.
Cassette 5B: One lymph node bisected.

- 6) Received labeled with the patient's name and "cervical biopsy tumor" is a pale pink tan hemorrhagic tissue fragment, 1.1 x 0.7 x 0.4 cm. The specimen is entirely submitted in cassette #6.

- 7) Received labeled with the patient's name and "left external iliac" is a 4.4 x 3.0 x 1.2 cm aggregate of pink to pale tan to yellow gold portions of fibroadipose tissue dissected for possible lymph nodes. Five possible lymph nodes identified ranging from 0.5 cm to 1.7 cm in greatest dimension and submitted as follows:

CASSETTE SUMMARY

Cassette 7A: Three possible lymph nodes.
Cassette 7B: One lymph node trisected.
Cassettes 7C-7D: One lymph node serially sectioned, entirely submitted.

- 8) Received labeled with the patient's name and "left obturator" is a portion of yellow gold to pink tan fibroadipose tissue, 3.2 x 2.0 x 0.5 cm. The specimen is dissected for possible lymph nodes. Two possible lymph nodes identified ranging from 0.8 cm to 3.5 cm in greatest dimension and submitted as follows:

CASSETTE SUMMARY

Cassette 8A: One possible lymph node.

** CONTINUED ON NEXT PAGE **

[page 4 of 4]
GROSS DESCRIPTION: (continued)

Cassettes 8B: One lymph node trisected.

- 9) Received labeled with the patient's name and "left common iliac" is a 2.0 x 1.7 x 0.4 cm portion of yellow gold to pink tan fibroadipose tissue dissected for possible lymph nodes. One lymph node identified, 1.0 x 0.4 x 0.4 cm. The specimen is bisected and entirely submitted in cassette #9.
- 10) Received labeled with the patient's name and "left para-aortic" are two portions of yellow gold to pink tan fibroadipose tissue ranging from 1.0 cm to 1.5 cm in greatest dimension dissected for possible lymph nodes. Two possible lymph nodes identified ranging from 0.5 cm to 0.7 cm in greatest dimension and submitted as follows:

CASSETTE SUMMARY

Cassette 10: Two possible lymph nodes.

- 11) Received labeled with the patient's name and "left external iliac" are two portions of yellow gold to pink tan fibroadipose tissue ranging from 1.7 cm to 2.1 cm in greatest dimension dissected for possible lymph nodes. Two possible lymph nodes identified ranging from 0.7 cm to 1.1 cm in greatest dimension and submitted as follows:

CASSETTE SUMMARY

Cassette 11A: One lymph node bisected.
Cassette 11B: One lymph node trisected.

Dictated :

Entered:

COPIES TO:

CPT Codes:

MUCICARMINE-88313/3999050, CERVICAL BIOPSY (1)/88305/3997100,
LYMPH NODE BIOPSY (M)/88305/3998021/2, LYMPH NODE, REGIONAL RESECT/88307/3998030/8

** CONTINUED ON NEXT PAGE **

Source: NCI Genomic Data Commons file c3787eee-6c53-463d-8450-435d74df88b1 (TCGA-EK-A2H0.AEDD5CA3-2E0A-414F-AA38-CCF5229EC7F2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).